Somatic mutation profile of tumor specimen MP2PRT-PAWALE-TMP1-A (aliquot MP2PRT-PAWALE-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAWALE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,823 days).
Specimen MP2PRT-PAWALE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97e689f9-5cb0-4b72-92ce-94a2c4048f61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWALE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWALE-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e2208be-f965-47fa-9fc6-0fae7e8de37e

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD4 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 70/406 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99163770; called by muse, mutect2, varscan2
- GRIN2B | c.2779C>T p.R927W | Missense Mutation (SNP) | VAF 134/500 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764278787, COSV74205048; called by muse, mutect2, varscan2
- MARCHF9 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 17/383 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as rs1437102996, COSV99874685; called by muse, mutect2
- NAA25 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 95/265 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV55701855; called by muse, mutect2, varscan2
- NSD2 | c.3374A>G p.D1125G | Missense Mutation (SNP) | VAF 29/311 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56397674; called by muse, mutect2
- OR51E2 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 130/437 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs530937980; called by muse, mutect2, varscan2
- PDE4DIP | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 90/268 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.408); catalogued as rs782553091; called by muse, varscan2
- SORCS2 | c.1828G>A p.G610R | Missense Mutation (SNP) | VAF 38/375 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206980180; called by muse, mutect2, varscan2
- STUM | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 114/439 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs754621069; called by muse, mutect2, varscan2
- TBPL2 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 30/240 reads (13%) | catalogued as rs746597775; called by muse, mutect2, varscan2
- TRPC5 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 237/561 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749694789, COSV53287947; called by muse, mutect2, varscan2
- UGT1A6 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 204/571 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765612353, COSV59388562, COSV59399731; called by muse, mutect2, varscan2
- LIPI | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- MAPK8IP3 | c.1564C>A p.R522S | Missense Mutation (SNP) | VAF 107/367 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VPS50 | c.1023G>C p.R341S | Missense Mutation (SNP) | VAF 28/480 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.122); called by muse, mutect2
- WDR44 | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 99/265 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- ZMAT1 | c.1835A>T p.K612M | Missense Mutation (SNP) | VAF 176/446 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CLSTN2 | c.2118G>A p.L706= | Silent (SNP) | VAF 32/479 reads (7%) | called by muse, mutect2
- GLIS3 | c.144G>A p.S48= | Silent (SNP) | VAF 74/288 reads (26%) | catalogued as rs148306701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2A | c.1491C>T p.I497= | Silent (SNP) | VAF 28/297 reads (9%) | catalogued as rs146157761, COSV58022441, COSV58042474; called by muse, mutect2, varscan2
- LSM7 | c.240C>G p.S80= | Silent (SNP) | VAF 30/608 reads (5%) | called by muse, mutect2
- MMP13 | c.663G>A p.A221= | Silent (SNP) | VAF 87/224 reads (39%) | catalogued as rs143331971; ClinVar: uncertain significance; called by muse, varscan2
- NLGN4X | c.240A>T p.S80= | Silent (SNP) | VAF 171/465 reads (37%) | called by muse, mutect2, varscan2
- NRXN1 | c.453C>T p.S151= | Silent (SNP) | VAF 182/500 reads (36%) | catalogued as rs774821523, COSV68007971, COSV68052403; called by muse, mutect2, varscan2
